TCGA case TCGA-02-0024 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0553e60e-3510-417d-af8a-75947ebe8ab6

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 35 years; Vital status: Dead; Days to death: 1,615 days (4.4 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 35.9 years (13,116 days); Year of diagnosis: 2000; Method of diagnosis: Surgical Resection; Prior treatment: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 33 days; Days to treatment end: 75 days; Treatment dose: 6,000 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 152 days; Days to treatment end: 701 days (1.9 years); Number of cycles: 18; Treatment dose: 3,600 mg/m2; Route of administration: Oral.
2. Recurrence of diagnosis 1 (Glioblastoma). Age at diagnosis: 39.7 years (14,517 days); Days to diagnosis: 1,401 days (3.8 years); Prior treatment: Yes.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 1,401 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 1,401 days (3.8 years).
- Days to follow up: 1,615 days (4.4 years); Disease response: With Tumor.
- Karnofsky performance status: 100.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-02-0024-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.7; Intermediate dimension: 0.7; Shortest dimension: 0.1.
  Slide TCGA-02-0024-01B-01-BS1: Section location: Bottom; Percent tumor cells: 50; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 40.
  Slide TCGA-02-0024-01B-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 20.
- Sample TCGA-02-0024-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-02-0024-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Treated primary GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: Yes; Method initial path diagnosis: Tumor resection.
- Drug treatment, Route of administrations: Route of administration: PO.

GDC annotations on this case (curator notes; quoted as recorded):
- Neoadjuvant therapy: Per enrollment form, patient received neo-adjuvant therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,615 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,615 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,401 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-02-0024-01): tumor purity 0.79, ploidy 3.81, whole-genome doublings 1 (call status: legacy_call).
